Somatic mutation profile of tumor specimen TCGA-OR-A5JF-01A (aliquot TCGA-OR-A5JF-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JF, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 69.8 years (25,502 days).
Specimen TCGA-OR-A5JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16118927-20c9-44fd-833d-ffaef65d86f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JF-10A (Blood Derived Normal), aliquot TCGA-OR-A5JF-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e9a65bf-4803-4961-bdb5-beb3a0800305

The open-access MAF lists 74 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Splice Site 2, Nonsense Mutation 1, 5'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPH | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753314715; called by muse, mutect2, varscan2
- ANK3 | c.12682G>A p.D4228N (on ENST00000280772 / NM_001320874.2; = p.D852N on NM_001149.3) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.829); catalogued as COSV55077166; called by muse, mutect2, varscan2
- ATP2C2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV52301002; called by muse, mutect2, varscan2
- ATRX | c.5262C>A p.N1754K | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM081519; called by muse, mutect2, varscan2
- CEL | c.2222C>T p.P741L (on ENST00000673714; = p.P738L on NM_001807.6) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs764851767; called by muse, mutect2, varscan2
- CLEC1A | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as rs771148686, COSV59531003; called by muse, mutect2, varscan2
- COL1A2 | c.2962G>C p.G988R | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51962764; called by muse, mutect2, varscan2
- CXorf38 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376500009; called by muse, mutect2, varscan2
- DSC2 | c.1783G>T p.V595F | Missense Mutation (SNP) | VAF 114/161 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV51866937; called by muse, mutect2, varscan2
- FLT4 | c.1894C>A p.R632S | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.176); catalogued as COSV56097784; called by muse, mutect2, varscan2
- PCDH11X | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as COSV100012812; called by muse, mutect2, varscan2
- RPGRIP1L | c.1244-1G>A p.X415_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100046192; called by muse, mutect2
- SMARCAL1 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 101/131 reads (77%) | catalogued as rs759179617; called by muse, varscan2
- SPATA31E1 | c.4328T>A p.L1443H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100351225; called by muse, mutect2
- STARD13 | c.387G>C p.K129N (on ENST00000336934 / NM_001243476.3; = p.K11N on NM_052851.3) | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs752755758; called by muse, mutect2, varscan2
- TPTE | c.1346G>A p.G449E (on ENST00000618007 / NM_199261.4; = p.G431E on NM_199259.4) | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs749783984; called by muse, mutect2
- USP51 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV101540685; called by muse, mutect2
- ZNRF4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs754757067; called by muse, mutect2, varscan2
- ACOT9 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- AGL | c.3725A>C p.D1242A | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- AMOTL2 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CADPS2 | c.1760G>C p.R587T | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEP152 | c.3105C>G p.I1035M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- COX4I1 | c.120T>G p.D40E | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCAF1 | c.2774C>G p.S925C | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- DHX57 | c.3216G>T p.M1072I | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EXT1 | c.2026A>G p.K676E | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- LCE1F | c.176G>C p.C59S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, varscan2
- LIG4 | c.1319C>G p.P440R | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINGO3 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MAP7D3 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS2 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PARP11 | c.733A>G p.S245G | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDE8B | c.2268T>G p.C756W | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PITPNM1 | c.2708A>G p.K903R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- PRRC2B | c.3842C>T p.S1281F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RAD9B | c.1033G>C p.A345P | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RARS2 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 98/137 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASGEF1B | c.892A>C p.N298H | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RBM12 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- RBM15 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 77/106 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RNF17 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RPAP2 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 69/87 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SLC35B1 | c.883T>A p.F295I (on ENST00000649906; = p.F258I on NM_005827.4) | Missense Mutation (SNP) | VAF 101/129 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SMC3 | c.1967A>G p.D656G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SREBF2 | c.108dup p.N37* | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- SULF1 | c.1421A>T p.H474L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SULF2 | c.2400G>C p.R800S | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAF1 | c.4840C>A p.L1614M (on ENST00000373790 / NM_138923.4; = p.L1635M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2
- TLR4 | c.799G>A p.G267R (on ENST00000355622 / NM_138554.5; = p.G227R on NM_003266.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPV4 | c.2176T>C p.S726P | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VAV3 | c.1457C>G p.T486R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13C | c.10003-1G>T p.X3335_splice (on ENST00000644861 / NM_020821.3; = p.X3292_splice on NM_017684.5) | Splice Site (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- ZC3H15 | c.1149G>T p.L383F | Missense Mutation (SNP) | VAF 74/104 reads (71%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZHX3 | c.2512G>C p.G838R | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZMAT1 | c.830T>C p.F277S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ADAMTS14 | c.1032C>G p.R344= | Silent (SNP) | VAF 68/128 reads (53%) | called by muse, mutect2, varscan2
- BTBD2 | c.540G>A p.S180= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs751988930; called by muse, mutect2
- CFAP46 | c.7623G>A p.A2541= | Silent (SNP) | VAF 161/298 reads (54%) | catalogued as rs368155362, COSV54148929; called by muse, mutect2, varscan2
- COL27A1 | c.4464C>T p.P1488= | Silent (SNP) | VAF 114/265 reads (43%) | catalogued as rs1265322353; called by muse, mutect2, varscan2
- FAM234B | c.1764G>A p.E588= | Silent (SNP) | VAF 112/231 reads (48%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.108C>A p.S36= | Silent (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- KCNK10 | c.1074C>A p.L358= | Silent (SNP) | VAF 96/136 reads (71%) | called by muse, mutect2, varscan2
- LMTK2 | c.1365G>A p.L455= | Silent (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- MEFV | c.1818C>G p.T606= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as rs104895213; called by muse, mutect2, varscan2
- PCDH7 | c.2163C>A p.P721= | Silent (SNP) | VAF 74/177 reads (42%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1860G>T p.G620= | Silent (SNP) | VAF 61/366 reads (17%) | called by muse, mutect2, varscan2
- RXRA | c.1149C>G p.L383= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- SEMG1 | c.288A>G p.S96= | Silent (SNP) | VAF 112/232 reads (48%) | catalogued as rs1322965462; called by muse, mutect2, varscan2
- SULF1 | c.1422C>T p.H474= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, varscan2
- TRAF2 | c.1236G>C p.V412= | Silent (SNP) | VAF 72/169 reads (43%) | called by muse, mutect2, varscan2
- TTI1 | c.765C>A p.I255= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- PRSS3 | c.-86T>A | 5'UTR (SNP) | VAF 176/448 reads (39%) | called by muse, varscan2
- TAOK2 | chr16:29991165 C>G | 3'Flank (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
